Somatic mutation profile of tumor specimen TCGA-AX-A064-01A (aliquot TCGA-AX-A064-01A-11W-A027-09) from TCGA case TCGA-AX-A064, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 81.1 years (29,625 days).
Specimen TCGA-AX-A064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f322afc2-3c42-4de1-8024-112559b2f1e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A064-10A (Blood Derived Normal), aliquot TCGA-AX-A064-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/084e0020-75ea-439b-8019-85ee232b258d

The open-access MAF lists 347 somatic variants for this specimen: 261 protein-altering or splice-affecting, 76 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 76, Frame Shift Del 45, Nonsense Mutation 9, Frame Shift Ins 9, Splice Site 9, In Frame Del 7, RNA 5, Splice Region 3, Intron 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.6313del p.I2105Yfs*14 | Frame Shift Del (DEL) | VAF 41/130 reads (32%) | catalogued as rs886040649; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 32/99 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 80/219 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 139/371 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.801+2T>C p.X267_splice | Splice Site (SNP) | VAF 108/282 reads (38%) | hotspot (GDC flag); catalogued as CS982334, COSV64291677, COSV64292074, COSV64301615; called by muse, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs533117495, COSV55946908; called by muse, mutect2, varscan2
- ACTA2 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV56515837; called by muse, mutect2, varscan2
- ACTN2 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs143150260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM22 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs558399747, COSV55971830; called by muse, mutect2, varscan2
- ADAM7 | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV51536294; called by muse, mutect2, varscan2
- ADAMTS16 | c.1499A>T p.E500V | Missense Mutation (SNP) | VAF 118/317 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56981745; called by muse, mutect2, varscan2
- ADAMTS3 | c.2207del p.P736Lfs*7 | Frame Shift Del (DEL) | VAF 48/337 reads (14%) | catalogued as rs34418522; called by mutect2, pindel, varscan2
- ADAMTS4 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV63489470; called by muse, mutect2
- ADAMTSL3 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 122/381 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54439643; called by muse, mutect2, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2, varscan2
- AGAP3 | c.375del p.X125_splice (on ENST00000622464; = p.X161_splice on NM_031946.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 8/50 reads (16%) | catalogued as rs758833571; called by mutect2, varscan2
- AHNAK | c.1777A>G p.R593G | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV57206250; called by muse, mutect2, varscan2
- AKR7A3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64389097; called by muse, mutect2, varscan2
- AMY2B | c.564T>A p.D188E | Missense Mutation (SNP) | VAF 319/838 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV63714390; called by muse, mutect2, varscan2
- ANGPTL7 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs924321890, COSV63869151; called by muse, mutect2, varscan2
- ARHGAP44 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs1164451727, COSV52390496; called by muse, mutect2, varscan2
- ATP1A4 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980110770, COSV63625778; called by muse, mutect2, varscan2
- BAZ2B | c.6446C>T p.A2149V | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58597022; called by muse, mutect2, varscan2
- BEST3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58299538; called by muse, mutect2, varscan2
- BICC1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332827341, COSV65857430; called by muse, mutect2, varscan2
- BRIP1 | c.262_264del p.C88del | In Frame Del (DEL) | VAF 107/324 reads (33%) | catalogued as rs587781388; called by pindel, varscan2
- BTG3 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV60286280; called by muse, mutect2, varscan2
- C11orf54 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58679539; called by muse, mutect2
- CACNB1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs772819208, COSV59998244; called by muse, mutect2, varscan2
- CAND1 | c.2825G>A p.C942Y | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); catalogued as rs1412655474, COSV73389519, COSV73389551; called by muse, mutect2, varscan2
- CCDC77 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV53472202; called by muse, mutect2
- CCNA1 | c.1065A>C p.Q355H | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs756868331, COSV55220362; called by muse, mutect2
- CCT8L2 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs372231331; called by muse, mutect2, varscan2
- CD101 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs1337687739, COSV56716700; called by muse, mutect2, varscan2
- CD109 | c.3707C>T p.A1236V | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV54646514; called by muse, mutect2, varscan2
- CD99L2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as rs782262501, COSV100691890, COSV60935265; called by muse, mutect2, varscan2
- CDHR4 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV58525879; called by muse, mutect2, varscan2
- CDX4 | c.649-2A>G p.X217_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV65171503; called by muse, mutect2, varscan2
- CEP128 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53673071; called by muse, mutect2, varscan2
- CER1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as rs765944833, COSV66603004; called by muse, mutect2, varscan2
- CHRNB1 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); catalogued as COSV60139358; called by muse, mutect2, varscan2
- CMYA5 | c.11554A>G p.R3852G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71404477; called by muse, mutect2
- CNGA3 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs201877346, COSV55622962; called by muse, mutect2, varscan2
- CNR2 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65692381, COSV65694779; called by muse, mutect2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 88/254 reads (35%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL8A1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53730770; called by muse, mutect2, varscan2
- COL9A2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs369221204; called by muse, mutect2, varscan2
- CR1 | c.4921C>T p.P1641S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1319989653, COSV65456596, COSV65461013; called by muse, mutect2, varscan2
- CSNK1G3 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs751857393, COSV62053684; called by muse, mutect2, varscan2
- CSRNP2 | c.1020_1022del p.E340del | In Frame Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs749407567; called by pindel, varscan2
- CUL1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV57387282; called by muse, mutect2, varscan2
- DCTN5 | c.27_29del p.N9del | In Frame Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs779696050; called by pindel, varscan2
- DDX20 | c.1274T>A p.I425N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63830878; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs766714372; called by mutect2, varscan2
- DENND11 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as rs781700741, COSV72097614; called by muse, mutect2, varscan2
- DHODH | c.435-2A>G p.X145_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV54661404; called by muse, mutect2
- DNAH1 | c.5720C>T p.T1907M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1372205755, COSV70227091; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs751671358; called by mutect2, varscan2
- DSC3 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs377721860; called by muse, mutect2, varscan2
- DST | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV100421872, COSV100422124; called by muse, mutect2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DVL2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs780268199, COSV50034912; called by muse, mutect2, varscan2
- EDN3 | c.629T>C p.L210P (on ENST00000337938 / NM_001302455.2; = p.L196P on NM_207033.3) | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV61107047; called by muse, mutect2, varscan2
- EFCAB13 | c.2277C>T p.N759= | Splice Region (SNP) | VAF 212/573 reads (37%) | catalogued as rs200981677, COSV58946368, COSV58946892; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as rs756407271; called by mutect2, pindel
- ERBB2 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54065427; called by muse, mutect2, varscan2
- ETS2 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV62872478; called by muse, mutect2, varscan2
- EXOSC5 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55370688; called by muse, mutect2, varscan2
- FAM161A | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.186); catalogued as COSV56764669; called by muse, mutect2, varscan2
- FAM47C | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV63724565; called by muse, mutect2
- FARP1 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757781772, COSV60332052; called by muse, mutect2, varscan2
- FBN3 | c.5069C>T p.A1690V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV54455483; called by muse, mutect2, varscan2
- FBXL5 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV58010105; called by muse, mutect2, varscan2
- FBXO11 | c.1530del p.G511Efs*6 (on ENST00000403359 / NM_001190274.2; = p.G427Efs*6 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as COSV57016953; called by mutect2, pindel, varscan2
- FBXO32 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762498343, COSV54890439; called by muse, mutect2, varscan2
- FER1L6 | c.1949dup p.P651Afs*11 | Frame Shift Ins (INS) | VAF 77/249 reads (31%) | catalogued as rs765775004; called by mutect2, varscan2
- FIGN | c.1277T>C p.V426A | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60764070; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs1216734611; called by mutect2, varscan2
- FMN2 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 54/226 reads (24%) | catalogued as rs1426355851, COSV60421234; called by muse, varscan2
- FSCN3 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV50000421; called by muse, mutect2, varscan2
- GABRG2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 145/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62715377, COSV62715450; called by muse, mutect2, varscan2
- GARNL3 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59224411; called by muse, mutect2
- GC | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV56735888; called by muse, mutect2, varscan2
- GPC5 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as rs775146119, COSV65577492, COSV65583949; called by muse, mutect2, varscan2
- GRIA2 | c.2468del p.G823Afs*10 | Frame Shift Del (DEL) | VAF 67/176 reads (38%) | catalogued as COSV52397066; called by mutect2, pindel, varscan2
- GRIPAP1 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64551279; called by muse, mutect2, varscan2
- HAL | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV54116811; called by muse, mutect2
- HEPH | c.2268G>A p.W756* (on ENST00000343002; = p.W489* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 49/151 reads (32%) | catalogued as COSV57960489; called by muse, mutect2, varscan2
- HERC6 | c.1988dup p.D664Gfs*2 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs780888205; called by mutect2, varscan2
- HMCN1 | c.11552A>G p.N3851S | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as rs1558234811, COSV54884117; called by muse, mutect2, varscan2
- HPS6 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as COSV54625049; called by muse, mutect2, varscan2
- HSPG2 | c.11497C>A p.H3833N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV65932843; called by muse, mutect2, varscan2
- IDH3B | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61389167; called by muse, mutect2, varscan2
- IFI44 | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV66074253; called by muse, mutect2, varscan2
- IGHV5-51 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1231968641; called by muse, mutect2, varscan2
- IGSF9 | c.1969G>A p.V657I (on ENST00000368094 / NM_001135050.2; = p.V641I on NM_020789.4) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63639187; called by muse, mutect2, varscan2
- IKZF3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53100410; called by muse, mutect2, varscan2
- ITLN1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58274505; called by muse, mutect2
- ITSN1 | c.2088del p.G697Afs*44 | Frame Shift Del (DEL) | VAF 51/131 reads (39%) | catalogued as COSV66085459; called by mutect2, pindel, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 185/496 reads (37%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNQ3 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754551218, COSV66463240, COSV66465621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5B | c.2774A>G p.Q925R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV52505341, COSV52506570; called by muse, mutect2, varscan2
- KIAA0232 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV56923831; called by muse, mutect2, varscan2
- KIF26B | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 27/209 reads (13%) | catalogued as rs1322066855, COSV69458002; called by muse, mutect2, varscan2
- KRT222 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV67497872, COSV67498194; called by muse, mutect2, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 57/185 reads (31%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LAMC1 | c.4487C>T p.A1496V | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV51134218; called by muse, mutect2, varscan2
- LONRF2 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs766141462, COSV66539743; called by muse, mutect2, varscan2
- LRP2BP | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60749440; called by muse, mutect2, varscan2
- LRRC3B | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV67520379, COSV67520662; called by muse, mutect2, varscan2
- LRRFIP2 | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60866575; called by muse, mutect2, varscan2
- LRRK2 | c.4174G>T p.V1392L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV54146889; called by muse, mutect2, varscan2
- MAP3K7 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV65223748; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | catalogued as rs780635289; called by mutect2, varscan2
- MICAL2 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as rs200483678; called by muse, mutect2, varscan2
- MOGS | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52027694; called by muse, mutect2, varscan2
- MPP6 | c.917dup p.K307Efs*14 | Frame Shift Ins (INS) | VAF 104/314 reads (33%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MTFR1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV50951297; called by muse, mutect2, varscan2
- MTHFD2L | c.572C>T p.A191V (on ENST00000395759 / NM_001144978.2; = p.A133V on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV57466383; called by muse, varscan2
- MTM1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 46/656 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60334063; called by muse, mutect2
- MTMR7 | c.980T>G p.V327G | Missense Mutation (SNP) | VAF 33/636 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV51663896; called by muse, mutect2
- MXRA5 | c.7315C>T p.P2439S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV54227670; called by muse, varscan2
- NCKAP5 | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200882141, COSV58427315; called by muse, mutect2, varscan2
- NCOA1 | c.1283G>A p.S428N | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56040474; called by muse, mutect2
- NEIL3 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 138/406 reads (34%) | catalogued as rs1444860795, COSV52808977; called by muse, mutect2, varscan2
- NEK2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65355346; called by muse, mutect2, varscan2
- NEK9 | c.2605-2A>G p.X869_splice | Splice Site (SNP) | VAF 26/70 reads (37%) | catalogued as COSV53129731; called by muse, mutect2, varscan2
- NELFCD | c.1621T>C p.Y541H (on ENST00000602795; = p.Y523H on NM_198976.4) | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV53882657; called by muse, mutect2
- NENF | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs199958962, COSV65341050; called by muse, mutect2, varscan2
- NOL8 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs772631824, COSV62634475; called by muse, mutect2, varscan2
- NOM1 | c.2092C>A p.L698I | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV51979195; called by muse, mutect2, varscan2
- NUCB1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV54385453; called by muse, mutect2
- NUP205 | c.4003G>C p.V1335L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV53656108; called by muse, mutect2, varscan2
- NUP214 | c.4733G>T p.R1578M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV63908183; called by muse, mutect2
- NVL | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55870852; called by muse, mutect2, varscan2
- OR3A2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101375082, COSV68694971; called by muse, mutect2, varscan2
- OR52E2 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV58612085; called by muse, mutect2, varscan2
- PABPC3 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs563373116, COSV55798181; called by muse, mutect2, varscan2
- PCDH11X | c.2616G>C p.K872N | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.95); catalogued as COSV53450013; called by muse, mutect2, varscan2
- PCDHB9 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV53376306; called by muse, mutect2, varscan2
- PCIF1 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV65026162; called by muse, mutect2, varscan2
- PHC3 | c.2642G>A p.R881H (on ENST00000494943 / NM_001308116.2; = p.R893H on NM_024947.4) | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs766618423, COSV71948450; called by muse, mutect2, varscan2
- PID1 | c.569A>G p.D190G (on ENST00000354069 / NM_001330156.1; = p.D188G on NM_017933.5) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV62473449; called by muse, mutect2, varscan2
- PIGC | c.536T>C p.L179S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51129651; called by muse, mutect2, varscan2
- PIK3CB | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100006296, COSV56684058; called by muse, varscan2
- PIK3R3 | c.1321_1323del p.N441del | In Frame Del (DEL) | VAF 38/157 reads (24%) | catalogued as rs1557544840; called by mutect2, pindel, varscan2
- PKHD1 | c.3864dup p.K1289Efs*8 | Frame Shift Ins (INS) | VAF 37/103 reads (36%) | catalogued as rs777925360; called by mutect2, pindel, varscan2
- PLEC | c.12773T>G p.L4258R (on ENST00000322810 / NM_201380.4; = p.L4148R on NM_000445.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100515192; called by muse, mutect2, varscan2
- PRDM10 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1000002154, COSV58799846; called by muse, mutect2, varscan2
- PRKDC | c.3944C>A p.T1315N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV58046374; called by muse, mutect2
- PRRC2A | c.3697G>T p.G1233C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV65685499; called by muse, varscan2
- PRRC2A | c.3753G>T p.Q1251H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65685504; called by muse, varscan2
- PRUNE2 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as COSV65038800; called by muse, mutect2, varscan2
- PTPRC | c.2375A>G p.Y792C | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765375367, COSV61408027; called by muse, mutect2, varscan2
- PTPRH | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs751095187, COSV54743484; called by muse, mutect2, varscan2
- RAE1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs779378832, COSV64797881; called by muse, mutect2, varscan2
- RAG2 | c.1307C>G p.T436S | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57556748; called by muse, mutect2, varscan2
- RAG2 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV57556755; called by muse, mutect2, varscan2
- RCBTB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs371439325; called by muse, mutect2, varscan2
- RLF | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65650954; called by muse, mutect2
- RPA3 | c.175-2A>G p.X59_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | catalogued as COSV56187653; called by muse, mutect2, varscan2
- RPTOR | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60804790; called by muse, mutect2, varscan2
- RTKN | c.871C>T p.P291S (on ENST00000272430 / NM_001015055.2; = p.P278S on NM_033046.2) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51961899; called by muse, mutect2, varscan2
- RTTN | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 121/381 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs776764068, COSV55342405; called by muse, mutect2, varscan2
- RYR2 | c.7607C>T p.A2536V | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63669879, COSV63670473; called by muse, mutect2, varscan2
- SBF2 | c.3145A>G p.R1049G | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV56293966; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs757259031; called by mutect2, varscan2
- SCML2 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363914629, COSV52619114; called by muse, mutect2, varscan2
- SCN1A | c.5552C>T p.A1851V (on ENST00000303395 / NM_001202435.3; = p.A1840V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV57663380; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SIDT1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV53499140; called by muse, mutect2, varscan2
- SLC25A52 | c.311C>T p.T104M (on ENST00000672005; = p.T94M on NM_001034172.4) | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1568006691, COSV52501839; called by muse, mutect2, varscan2
- SLC38A5 | c.1318-1G>T p.X440_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100476572; called by muse, mutect2
- SLC39A6 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52368223; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A1AP | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1354643142, COSV58134019; called by muse, mutect2, varscan2
- SLX4 | c.2388G>T p.E796D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV53561984; called by muse, mutect2, varscan2
- SMOX | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53863431; called by muse, mutect2
- SMPD3 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV54710921; called by muse, mutect2, varscan2
- SNTG1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs1248076375, COSV52430689; called by muse, mutect2, varscan2
- SNX11 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 134/375 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs376112408; called by muse, mutect2, varscan2
- SOWAHC | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV61779625; called by muse, mutect2, varscan2
- SPDYC | c.846C>T p.R282= | Splice Region (SNP) | VAF 35/66 reads (53%) | catalogued as COSV65864963; called by muse, mutect2, varscan2
- SSMEM1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as COSV52833210, COSV52833914; called by muse, mutect2, varscan2
- SVIL | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV63441025; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 41/318 reads (13%) | catalogued as rs570102997; called by mutect2, varscan2
- SYDE2 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV52314537; called by muse, mutect2, varscan2
- SYNCRIP | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 151/348 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62287015; called by muse, mutect2, varscan2
- TAF1 | c.2175C>G p.N725K (on ENST00000373790 / NM_138923.4; = p.N746K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52108890; called by muse, mutect2, varscan2
- TAF5L | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV51077964; called by muse, mutect2, varscan2
- TASOR2 | c.5240T>C p.V1747A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60166091; called by muse, mutect2, varscan2
- TBKBP1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 50/130 reads (38%) | catalogued as rs1009893679, COSV64653327; called by muse, mutect2, varscan2
- TG | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV55068566; called by muse, mutect2, varscan2
- TJP2 | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55263671; called by muse, mutect2, varscan2
- TMC1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52769355; called by muse, mutect2
- TNR | c.3854T>C p.V1285A | Missense Mutation (SNP) | VAF 114/605 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV54875005, COSV54902626; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs770561785; called by mutect2, varscan2
- TRAT1 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV55467551, COSV55467662; called by muse, mutect2, varscan2
- TRIM2 | c.1579G>A p.G527R (on ENST00000437508; = p.G554R on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58631843; called by muse, mutect2
- TRIM23 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.833); catalogued as rs371065655; called by muse, mutect2, varscan2
- TRPM6 | c.5776+1G>A p.X1926_splice | Splice Site (SNP) | VAF 44/156 reads (28%) | catalogued as COSV62504596; called by muse, mutect2, varscan2
- TTN | c.63337G>A p.D21113N (on ENST00000591111; = p.D13689N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | PolyPhen benign (0.022); catalogued as rs755823330, COSV59931704; called by muse, mutect2, varscan2
- TTN | c.9448C>T p.R3150* (on ENST00000591111; = p.R3104* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 108/312 reads (35%) | catalogued as rs146572907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1372337465, COSV53303845; called by muse, mutect2, varscan2
- TUBGCP6 | c.2155-2A>G p.X719_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV50538483; called by muse, mutect2, varscan2
- UBE4B | c.1801G>A p.A601T (on ENST00000343090 / NM_001105562.3; = p.A472T on NM_006048.5) | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53528484; called by muse, mutect2, varscan2
- UNC50 | c.533del p.F178Sfs*7 | Frame Shift Del (DEL) | VAF 91/314 reads (29%) | catalogued as rs752307344; called by mutect2, pindel, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs767420916; called by mutect2, varscan2
- UTP20 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1377258496, COSV55373718; called by muse, mutect2, varscan2
- VPS13A | c.2873T>C p.M958T | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62426313; called by muse, mutect2, varscan2
- WDHD1 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59460109; called by muse, mutect2, varscan2
- ZC3H15 | c.971A>C p.D324A | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61921878; called by muse, mutect2, varscan2
- ZDHHC5 | c.228T>C p.A76= | Splice Region (SNP) | VAF 31/90 reads (34%) | catalogued as COSV54705525; called by muse, mutect2, varscan2
- ZNF2 | c.1204C>T p.R402C (on ENST00000611147 / NM_001291605.2; = p.R389C on NM_021088.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1225735714, COSV54636359; called by muse, mutect2, varscan2
- ZNF320 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 136/364 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1028712976, COSV67087704; called by muse, mutect2, varscan2
- ZNF384 | c.1271C>T p.T424M (on ENST00000361959; = p.T363M on NM_133476.5) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60528888; called by muse, mutect2, varscan2
- ZNF423 | c.3676A>G p.I1226V (on ENST00000563137 / NM_001379286.1; = p.I1218V on NM_015069.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52180705; called by muse, mutect2, varscan2
- ZNF425 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 8/193 reads (4%) | catalogued as COSV65200781; called by muse, mutect2
- ZNF491 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 55/160 reads (34%) | catalogued as rs377331762, COSV60056699; called by muse, mutect2, varscan2
- ZNF572 | c.850A>C p.S284R | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV60001432; called by muse, mutect2
- ZNF630 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52095240; called by muse, mutect2
- ZNF684 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV65518894; called by muse, mutect2
- ZNF71 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV60146966; called by muse, mutect2, varscan2
- ZNF835 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV73379256; called by muse, mutect2, varscan2
- ZNFX1 | c.5578T>A p.C1860S | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV65595038; called by muse, mutect2, varscan2
- ZXDB | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1287059051, COSV66492483, COSV66493431; called by muse, mutect2, varscan2
- ABCA10 | c.990del p.F330Lfs*39 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | called by mutect2, pindel, varscan2
- AK3 | c.368_370del p.Q123del | In Frame Del (DEL) | VAF 18/54 reads (33%) | called by pindel, varscan2
- ARHGAP35 | c.4283_4284del p.F1428Yfs*87 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | called by mutect2, pindel, varscan2
- ARID1A | c.4220del p.P1407Qfs*74 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- CD4 | c.350_352del p.E117del | In Frame Del (DEL) | VAF 36/120 reads (30%) | called by pindel, varscan2
- CFAP70 | c.694dup p.I232Nfs*10 | Frame Shift Ins (INS) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- DDC | c.953del p.K318Rfs*5 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- DLGAP5 | c.431del p.K144Rfs*55 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, varscan2
- DUS4L | c.886del p.R296Gfs*13 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.8283del p.F2761Lfs*20 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel, varscan2
- ERBB2 | c.3694del p.A1232Lfs*70 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.2403dup p.G802Wfs*63 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- H1-3 | c.555del p.A186Lfs*? | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.4454del p.K1485Rfs*85 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1322del p.N441Tfs*2 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- IPO4 | c.1038del p.E347Rfs*7 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- KCTD13 | c.886del p.E296Rfs*37 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- LRP1 | c.4468del p.E1490Rfs*80 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel
- LSM14A | c.728_729del p.K243Sfs*7 | Frame Shift Del (DEL) | VAF 64/187 reads (34%) | called by mutect2, pindel, varscan2
- LY75 | c.1572dup p.G525Wfs*10 | Frame Shift Ins (INS) | VAF 19/158 reads (12%) | called by mutect2, pindel, varscan2
- MASTL | c.1372del p.I458Lfs*9 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | called by mutect2, pindel, varscan2
- MTIF2 | c.1767del p.G590Efs*2 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | called by mutect2, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- RELN | c.908del p.P303Lfs*33 | Frame Shift Del (DEL) | VAF 144/463 reads (31%) | called by mutect2, pindel, varscan2
- RGS3 | c.2312del p.P771Lfs*64 (on ENST00000350696 / NM_001282923.2; = p.P490Lfs*64 on NM_130795.4) | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- RNF38 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETX | c.3872dup p.P1293Sfs*3 | Frame Shift Ins (INS) | VAF 129/388 reads (33%) | called by mutect2, varscan2
- SRP14 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF4 | c.1395_1397del p.L466del | In Frame Del (DEL) | VAF 14/45 reads (31%) | called by pindel, varscan2
- TNRC6B | c.2251dup p.E751Gfs*17 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- VPS4B | c.592del p.S198Qfs*12 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3949G>T p.A1317S (on ENST00000336378; = p.A1296S on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 168/247 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZFHX3 | c.5909del p.K1970Rfs*27 | Frame Shift Del (DEL) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4041T>C p.A1347= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV70026529; called by muse, mutect2, varscan2
- ABO | c.909C>T p.S303= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV71743452; called by muse, mutect2, varscan2
- ACSBG2 | c.1173T>C p.C391= | Silent (SNP) | VAF 11/176 reads (6%) | catalogued as COSV53123359; called by muse, mutect2
- AHCYL2 | c.528G>A p.Q176= | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as rs1213330218, COSV61485694; called by muse, mutect2, varscan2
- ALB | c.1554T>C p.D518= | Silent (SNP) | VAF 96/244 reads (39%) | catalogued as COSV55736385; called by muse, mutect2, varscan2
- ATIC | c.1185C>T p.V395= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as rs1349695082, COSV52692247; called by muse, mutect2, varscan2
- C1orf127 | c.1452G>T p.S484= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100983433, COSV65436661; called by muse, varscan2
- CD276 | c.1350C>T p.H450= (on ENST00000318443 / NM_001024736.2; = p.H232= on NM_025240.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs981132326, COSV59202922; called by muse, mutect2
- CELSR3 | c.3993G>A p.S1331= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1559481240, COSV50841785; called by muse, mutect2
- CLDN8 | c.333T>C p.N111= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV54525607; called by muse, mutect2, varscan2
- CNNM1 | c.2427C>T p.D809= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs532479735, COSV63200777; called by muse, mutect2, varscan2
- CRELD1 | c.1125C>A p.I375= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV55976562; called by muse, mutect2, varscan2
- CTH | c.699T>C p.H233= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV61007579; called by muse, mutect2, varscan2
- DHX35 | c.915G>A p.G305= | Silent (SNP) | VAF 14/191 reads (7%) | catalogued as COSV52668277; called by muse, mutect2
- DICER1 | c.2031C>A p.A677= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as COSV58616667; called by muse, mutect2
- DSCAM | c.2250G>A p.S750= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs139291190; called by muse, mutect2, varscan2
- DUS2 | c.1239C>T p.T413= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs747872703, COSV62708035; called by muse, mutect2, varscan2
- ESYT3 | c.2142C>T p.F714= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs760771152, COSV67440437; called by muse, mutect2, varscan2
- FAM193A | c.1848G>A p.T616= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs765066398, COSV61191873; called by muse, mutect2, varscan2
- FERMT3 | c.120G>A p.S40= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs770220477, COSV54177726; called by muse, mutect2, varscan2
- FHOD3 | c.3114C>A p.S1038= (on ENST00000359247 / NM_001281739.3; = p.S1055= on NM_025135.5) | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV57167109; called by muse, mutect2, varscan2
- FOXD4L5 | c.861C>T p.G287= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV66241341; called by mutect2, varscan2
- GBE1 | c.1401G>A p.R467= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV70097571; called by muse, mutect2, varscan2
- GPAT4 | c.1200C>T p.V400= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV67840395; called by muse, mutect2, varscan2
- GPM6B | c.471C>A p.P157= | Silent (SNP) | VAF 108/282 reads (38%) | catalogued as COSV100366613, COSV57421603; called by muse, mutect2, varscan2
- HOXB1 | c.882C>A p.A294= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53316660; called by muse, mutect2
- HSD11B1 | c.138C>T p.I46= | Silent (SNP) | VAF 53/294 reads (18%) | catalogued as rs149277936; called by muse, mutect2, varscan2
- ICAM5 | c.1197C>T p.S399= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV55746407; called by muse, mutect2, varscan2
- IDO2 | c.1203A>G p.S401= (on ENST00000389060; = p.S414= on NM_194294.2) | Silent (SNP) | VAF 79/226 reads (35%) | catalogued as COSV58424181; called by muse, mutect2, varscan2
- INAVA | c.546C>T p.H182= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV66256077; called by muse, mutect2, varscan2
- KCNA10 | c.207C>T p.D69= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs921489394, COSV63904298; called by muse, mutect2, varscan2
- KCNQ5 | c.495C>T p.F165= | Silent (SNP) | VAF 189/483 reads (39%) | catalogued as rs777287414, COSV59650187; called by muse, mutect2, varscan2
- KNDC1 | c.4605A>G p.L1535= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV58832840; called by muse, mutect2, varscan2
- KSR2 | c.525G>A p.T175= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs751706259, COSV60369016; called by muse, mutect2
- LIFR | c.1665T>C p.Y555= | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as COSV54685971; called by muse, mutect2
- LRRC19 | c.1089C>A p.I363= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs770541602, COSV66259362; called by muse, mutect2
- MYH14 | c.1863C>T p.N621= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs374682911; called by muse, mutect2
- NFRKB | c.660G>A p.P220= (on ENST00000446488 / NM_001143835.2; = p.P245= on NM_006165.3) | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs1006275391, COSV58756840; called by muse, mutect2, varscan2
- NLRP5 | c.2247C>T p.S749= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs149649207; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAP1 | c.546C>T p.S182= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs761309766, COSV61504000, COSV61505225; called by muse, mutect2, varscan2
- NPHP3 | c.3432A>G p.L1144= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs764978219, COSV58628725; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP214 | c.576G>T p.T192= | Silent (SNP) | VAF 98/232 reads (42%) | catalogued as COSV63908177; called by muse, mutect2, varscan2
- OR12D3 | c.561T>C p.C187= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as COSV65826762; called by muse, mutect2
- OR5R1 | c.360C>T p.Y120= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as rs750065461, COSV56571696; called by muse, mutect2
- OR8J1 | c.30T>C p.T10= | Silent (SNP) | VAF 124/363 reads (34%) | catalogued as COSV57316996; called by muse, mutect2, varscan2
- PANK2 | c.846G>A p.L282= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV57253367; called by muse, mutect2, varscan2
- PCDHA13 | c.1353C>T p.N451= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs368758287, COSV56484020; called by muse, mutect2, varscan2
- PCDHGC5 | c.2262C>T p.D754= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV52746188; called by muse, mutect2, varscan2
- PDS5A | c.2346C>T p.H782= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV57823566; called by muse, mutect2
- PLCG2 | c.3618G>A p.R1206= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs778651313, COSV63867907; called by muse, mutect2, varscan2
- QPCT | c.804C>T p.F268= | Silent (SNP) | VAF 136/412 reads (33%) | catalogued as rs769234907, COSV58118976; called by muse, mutect2, varscan2
- RAPGEF1 | c.714C>T p.D238= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV64698399; called by muse, mutect2, varscan2
- RBM12 | c.2697A>G p.E899= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV58290252; called by muse, mutect2, varscan2
- RGS5 | c.516C>T p.R172= | Silent (SNP) | VAF 84/422 reads (20%) | catalogued as COSV58351746; called by muse, mutect2, varscan2
- RNASEL | c.1443C>T p.Y481= | Silent (SNP) | VAF 110/438 reads (25%) | catalogued as COSV62376370; called by muse, mutect2, varscan2
- SCN3A | c.4920G>C p.G1640= | Silent (SNP) | VAF 58/374 reads (16%) | catalogued as COSV51804332; called by muse, mutect2, varscan2
- SEMA5B | c.1386C>A p.P462= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52092728; called by muse, mutect2
- SGSM3 | c.1287G>A p.T429= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs772671058, COSV50651363, COSV50652930; called by muse, mutect2, varscan2
- SLC39A14 | c.1035C>T p.G345= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV51482970; called by muse, mutect2, varscan2
- SLK | c.3126C>T p.H1042= | Silent (SNP) | VAF 31/310 reads (10%) | catalogued as rs760777100, COSV59824316; called by muse, mutect2, varscan2
- SMAD7 | c.765T>C p.P255= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV50988938; called by muse, mutect2, varscan2
- SPTBN4 | c.5898G>A p.G1966= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58945162; called by muse, mutect2, varscan2
- ST3GAL1 | c.420G>T p.R140= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV60610996; called by muse, mutect2, varscan2
- STT3A | c.955C>T p.L319= | Silent (SNP) | VAF 66/204 reads (32%) | catalogued as COSV67064331; called by muse, mutect2
- SYNPO2L | c.2142G>A p.P714= (on ENST00000394810 / NM_001114133.3; = p.P490= on NM_024875.5) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV65736322; called by muse, mutect2, varscan2
- TENM4 | c.2898C>T p.G966= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs770397552, COSV53614706; called by muse, mutect2, varscan2
- TFAP2D | c.30C>T p.H10= | Silent (SNP) | VAF 85/237 reads (36%) | catalogued as COSV50409851; called by muse, mutect2, varscan2
- THRAP3 | c.1137T>G p.S379= | Silent (SNP) | VAF 132/328 reads (40%) | catalogued as COSV63566943; called by muse, mutect2, varscan2
- TNXB | c.4665G>A p.A1555= (on ENST00000647633; = p.A1308= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs745464565, COSV64475095; called by muse, mutect2, varscan2
- TRIM5 | c.1092C>T p.D364= | Silent (SNP) | VAF 54/466 reads (12%) | catalogued as rs771111675, COSV59898928; called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2, varscan2
- USP6 | c.3444G>A p.S1148= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1164119104, COSV51472817; called by muse, mutect2, varscan2
- VPS35L | c.2457C>T p.R819= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1342059723, COSV51978537; called by muse, mutect2
- ZIC3 | c.1209G>A p.L403= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV54972817; called by muse, mutect2, varscan2
- ZNF184 | c.747C>A p.P249= | Silent (SNP) | VAF 135/413 reads (33%) | catalogued as COSV53003461; called by muse, mutect2, varscan2
- ZNF648 | c.960C>T p.S320= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1427286110, COSV60570056; called by muse, mutect2
- ARHGEF25 | chr12:57620392 A>G | 3'Flank (SNP) | VAF 66/523 reads (13%) | catalogued as rs1403866421, COSV54085072; called by muse, mutect2, varscan2
- CXCL12 | c.266+2635del | Intron (DEL) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- HOXB4 | chr17:48579946 del TCT | 5'Flank (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2
- OR2U1P | n.312G>A | RNA (SNP) | VAF 164/407 reads (40%) | catalogued as rs376061083; called by muse, mutect2, varscan2
- OR3A4P | n.867A>G | RNA (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- RN7SL106P | chr15:23163141 A>G | 5'Flank (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2
- RPS26P15 | n.332del | RNA (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- UGGT2 | c.3038+615del | Intron (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- XIST | n.8344G>A | RNA (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- XIST | n.7256A>G | RNA (SNP) | VAF 11/102 reads (11%) | called by mutect2, varscan2
